Surgical pathology report (de-identified scan), TCGA case TCGA-R8-A6MK, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MD Anderson, specimen TCGA-R8-A6MK-01A (Primary Tumor).

[page 1 of 2]
M

(178.0cm 86.2kg BSA: 2.06m²)

Accession:

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT FRONTAL BRAIN MASS
OLIGODENDROGLIOMA, GRADE 2 (WHO).
(B) RIGHT FRONTAL BRAIN MASS -
OLIGODENDROGLIOMA, GRADE 2 (WHO).

Entire report and diagnosis completed by

COMMENT

A 1p/19q analysis will be performed.

GROSS DESCRIPTION

(A) RIGHT FRONTAL BRAIN MASS FOR RESEARCH - The specimen consists of a piece of cerebral cortex and underlying white matter measuring 5.0 x 5.0 x 3.0 cm. On cut surface is a delineated gray-white junction seen in the majority of the specimen. However, a portion shows an obscure gray-white junction. This portion is submitted for frozen section and smear in cassette A1. An additional representative section is submitted in cassettes A2-A10. Specimens are also sent for research studies.

*FS/DX: LOW-INTERMEDIATE GRADE INFILTRATING GLIOMA.

(B) RIGHT FRONTAL BRAIN MASS - The specimen is received fresh in one container labeled with the patient's name, medical record number and designation as right frontal brain mass. The specimen consists of two irregular fragments of yellow to white-tan tissue. One fragment measures 3.2 x 2.4 x 0.7 cm and the other fragment measures 2.7 x 2.4 x 0.8 cm. The cut surface of the specimen is white to yellow-tan and homogeneous, no focal lesions are identified. The entire specimen is submitted for histologic examination.

SECTION CODE: B1-B3, larger fragment of the specimen submitted entirely; B4-B6, the smaller fragment of specimen submitted entirely.

SNOMED CODES

T-A2000, M-94503

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

Start of ADDENDUM

[page 2 of 2]
Page: 2

M

(178.0cm 86.2kg BSA: 2.06m²)

Accession:

Specimen Date/Time:

ADDENDUM

Real time PCR was performed for markers on chromosomes 1p and 19q and shows loss at both chromosomal arms. Combined 1p/19q loss has been shown to correlate with the oligodendroglial lineage and may predict a more favorable response to adjuvant therapy compared with tumors showing intact 1p/19q.

Entire report and diagnosis completed by

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file df075b31-cff7-4677-ac34-de0ad1968af1 (TCGA-R8-A6MK.0E083D5C-1EE1-4BDA-9D6E-93420C3BAE39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).